Somatic mutation profile of tumor specimen 0DC631 from CCDI case PBBLYZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.2 years (3,361 days).
Specimen 0DC631: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a23d7da-d67a-4ac5-b432-5129e2bb1db2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DC634 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1dbdb037-14cf-4af4-b037-e0777abcb782

The open-access MAF lists 16 somatic variants for this specimen: 6 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 7, Missense Mutation 6, 3'UTR 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNOT3 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 131/343 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55360199; called by muse, mutect2, varscan2
- GRAP2 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 311/697 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.745); catalogued as rs147808667, COSV59995565; called by muse, mutect2, varscan2
- CECR2 | c.424C>T p.L142F | Missense Mutation (SNP) | VAF 345/848 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FCRL3 | c.800A>C p.H267P | Missense Mutation (SNP) | VAF 50/990 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.01); called by muse, mutect2
- NUP155 | c.925G>A p.G309R (on ENST00000231498 / NM_153485.3; = p.G250R on NM_004298.4) | Missense Mutation (SNP) | VAF 415/1068 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZFX | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 36/1000 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2
- FHAD1 | c.459C>T p.P153= | Silent (SNP) | VAF 32/662 reads (5%) | called by muse, mutect2
- HNF1A | c.1245G>A p.G415= | Silent (SNP) | VAF 25/417 reads (6%) | catalogued as rs917606298, COSV99982855; called by muse, mutect2
- NFATC1 | c.120G>A p.A40= | Silent (SNP) | VAF 50/357 reads (14%) | called by muse, mutect2, varscan2
- OR7G2 | c.6G>A p.P2= | Silent (SNP) | VAF 420/967 reads (43%) | catalogued as rs1289574806, COSV59687389; called by muse, mutect2, varscan2
- SERPINA1 | c.846G>A p.G282= | Silent (SNP) | VAF 48/1125 reads (4%) | called by muse, mutect2
- SMARCD2 | c.60C>G p.A20= | Silent (SNP) | VAF 50/488 reads (10%) | called by mutect2, varscan2
- VPS13A | c.4836A>G p.P1612= | Silent (SNP) | VAF 382/901 reads (42%) | called by muse, mutect2, varscan2
- AP1S1 | c.*52G>A | 3'UTR (SNP) | VAF 92/313 reads (29%) | catalogued as rs554973542; called by muse, mutect2, varscan2
- GP2 | c.*19G>T | 3'UTR (SNP) | VAF 92/404 reads (23%) | called by muse, mutect2, varscan2
- IL31RA | c.*81G>A | 3'UTR (SNP) | VAF 20/67 reads (30%) | catalogued as rs1004671123; called by muse, mutect2
